Somatic mutation profile of tumor specimen TCGA-93-8067-01A (aliquot TCGA-93-8067-01A-11D-2284-08) from TCGA case TCGA-93-8067, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.9 years (28,453 days).
Specimen TCGA-93-8067-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68e4c04d-ce04-4ca0-81d6-78e684174317.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-93-8067-10A (Blood Derived Normal), aliquot TCGA-93-8067-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/972f35c2-a12e-4f0f-8603-d62c736d76b5

The open-access MAF lists 559 somatic variants for this specimen: 407 protein-altering or splice-affecting, 144 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 353, Silent 144, Nonsense Mutation 36, Splice Site 7, Frame Shift Del 5, Intron 4, Splice Region 2, Translation Start Site 2, Frame Shift Ins 2, RNA 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- GCK | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 75/161 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.318); catalogued as rs767565869, COSV100357249, COSV60787127; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NFE2L2 | c.70T>C p.W24R | Missense Mutation (SNP) | VAF 25/65 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1328994103, COSV67960091, COSV67960815, COSV67963035; called by muse, mutect2, varscan2
- SPATA5 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); catalogued as rs745858366, CM159204, COSV56785606, COSV99914630; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.6667G>C p.E2223Q | Missense Mutation (SNP) | VAF 51/268 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs368094089; called by muse, mutect2, varscan2
- ACER2 | c.654C>G p.I218M | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100575821, COSV100575892; called by muse, mutect2, varscan2
- ACTB | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); catalogued as rs1420193633, COSV100079696; called by muse, mutect2, varscan2
- ACTBL2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as rs749694409, COSV70661456; called by muse, mutect2, varscan2
- ADAM22 | c.2158G>C p.D720H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.14); catalogued as COSV99717188; called by muse, mutect2, varscan2
- ADAMTS2 | c.2858C>T p.S953F | Missense Mutation (SNP) | VAF 49/372 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV52371211; called by muse, mutect2, varscan2
- ADCY5 | c.1401C>A p.N467K | Missense Mutation (SNP) | VAF 62/405 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100567820, COSV59194839; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745856523, COSV58443114; called by muse, mutect2, varscan2
- ADGRG7 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.133); catalogued as COSV99841121; called by muse, mutect2, varscan2
- AHDC1 | c.3569C>G p.S1190* | Nonsense Mutation (SNP) | VAF 12/108 reads (11%) | catalogued as COSV99899403; called by muse, mutect2, varscan2
- AJM1 | c.1255G>C p.D419H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.54); catalogued as COSV99915711; called by muse, mutect2, varscan2
- AJM1 | c.2217C>G p.I739M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV56034445, COSV56034782; called by muse, mutect2, varscan2
- ALMS1 | c.3769C>T p.H1257Y | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV100042679; called by muse, mutect2, varscan2
- ALOX5AP | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as COSV100996296, COSV100996297; called by muse, mutect2, varscan2
- ANKMY1 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs768966375, COSV56030766; called by muse, mutect2, varscan2
- ANKRD12 | c.5419G>C p.E1807Q | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100041460; called by muse, mutect2, varscan2
- ANO5 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100201923, COSV61087861; called by muse, mutect2
- ANO6 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100263347; called by muse, mutect2, varscan2
- APOB | c.6139G>A p.E2047K | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as COSV99266011; called by muse, mutect2, varscan2
- APOL4 | c.470G>T p.G157V (on ENST00000352371 / NM_145660.2; = p.G154V on NM_030643.4) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100274130; called by muse, mutect2, varscan2
- ARHGAP6 | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100272988; called by muse, mutect2, varscan2
- ARHGEF18 | c.591G>C p.K197N (on ENST00000359920 / NM_001130955.2; = p.K93N on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/371 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as COSV100149595; called by muse, mutect2, varscan2
- ARHGEF26 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1402522310, COSV100726580; called by muse, mutect2, varscan2
- ARID2 | c.3298C>G p.Q1100E | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV57601004, COSV57608342; called by muse, mutect2, varscan2
- ARMH4 | c.1190C>G p.S397C | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs754302637, COSV50767350, COSV99958351; called by muse, mutect2, varscan2
- ASCC2 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100316306; called by muse, mutect2, varscan2
- ATAD3B | c.586C>T p.Q196* (on ENST00000308647; = p.Q302* on NM_031921.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/93 reads (8%) | catalogued as COSV100426505; called by muse, mutect2
- ATXN7L1 | c.321G>C p.Q107H | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as COSV100596886; called by muse, mutect2, varscan2
- B2M | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 51/127 reads (40%) | catalogued as COSV62563917; called by muse, mutect2, varscan2
- B2M | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV100837670; called by muse, mutect2, varscan2
- B3GALT4 | c.602G>C p.R201T | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.229); catalogued as COSV101005646; called by muse, mutect2, varscan2
- BCAN | c.2183C>A p.T728K | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100228173; called by muse, mutect2, varscan2
- BCL3 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99378191; called by muse, mutect2, varscan2
- BFSP2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 41/219 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV100183788; called by muse, mutect2, varscan2
- BOD1L1 | c.3309G>T p.Q1103H | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99239546; called by muse, mutect2, varscan2
- BPHL | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100984488, COSV66744112; called by muse, mutect2, varscan2
- BPTF | c.3451G>C p.E1151Q | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV100075117; called by muse, mutect2, varscan2
- BRIP1 | c.3538G>C p.D1180H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV99370301; called by muse, mutect2, varscan2
- BRWD1 | c.5928G>C p.L1976F | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.146); catalogued as rs779164639, COSV100313547; called by muse, mutect2, varscan2
- C11orf1 | c.344-1G>T p.X115_splice | Splice Site (SNP) | VAF 20/64 reads (31%) | catalogued as rs145116726, COSV99499970; called by muse, mutect2, varscan2
- C21orf58 | c.444+1G>A p.X148_splice | Splice Site (SNP) | VAF 15/82 reads (18%) | catalogued as COSV99388072; called by muse, mutect2, varscan2
- C2CD5 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1230288897, COSV100448633, COSV100448815; called by muse, mutect2, varscan2
- C8orf76 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374975138, COSV99414859; called by muse, mutect2, varscan2
- C9orf50 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 15/227 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs535635348, COSV100992334; called by muse, mutect2
- CACNA1G | c.6618G>C p.K2206N | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.013); catalogued as COSV100661330, COSV100661930; called by muse, mutect2
- CACNB3 | c.50C>G p.S17* | Nonsense Mutation (SNP) | VAF 16/128 reads (13%) | catalogued as COSV99974929; called by muse, mutect2, varscan2
- CCDC70 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV54430525, COSV99665370; called by muse, mutect2, varscan2
- CD163L1 | c.3996G>C p.Q1332H | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.055); catalogued as COSV100550158; called by muse, mutect2
- CD209 | c.714C>G p.I238M | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.609); catalogued as rs1356104625, COSV99214041; called by muse, varscan2
- CD47 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.166); catalogued as rs1308525788, COSV100790124; called by muse, mutect2, varscan2
- CEMIP2 | c.2377G>C p.D793H | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100987404; called by muse, mutect2, varscan2
- CEP104 | c.892-1G>C p.X298_splice | Splice Site (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100986634; called by muse, mutect2, varscan2
- CER1 | c.504C>A p.S168R | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV101097841; called by muse, mutect2, varscan2
- CFAP91 | c.335G>C p.R112T | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.167); catalogued as COSV99847170; called by muse, mutect2
- CGREF1 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV99565196; called by muse, mutect2, varscan2
- CHAF1A | c.1692G>C p.E564D | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100011258; called by muse, mutect2, varscan2
- CHAF1A | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV56673446; called by muse, varscan2
- CHD9 | c.7377A>C p.L2459F (on ENST00000398510 / NM_001382353.1; = p.L2443F on NM_025134.7) | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.091); catalogued as COSV99529244; called by muse, mutect2, varscan2
- CHEK2 | c.46A>C p.S16R | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.069); catalogued as rs1426424086, COSV100101834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLIP1 | c.4199C>T p.S1400L (on ENST00000620786 / NM_001247997.1; = p.S1389L on NM_002956.2) | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs965447390, COSV100211850; called by muse, mutect2, varscan2
- CLIP3 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1342311626, COSV99431117; called by muse, mutect2, varscan2
- CLTC | c.2115C>G p.F705L | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52253768; called by muse, mutect2, varscan2
- CMTR2 | c.337C>G p.Q113E | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100579196, COSV57602503; called by muse, mutect2, varscan2
- CNBD2 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100839009, COSV100839113; called by muse, mutect2, varscan2
- CNTN3 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs1350870526, COSV55173355; called by muse, mutect2, varscan2
- COL16A1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99594644; called by muse, mutect2, varscan2
- COP1 | c.1162C>G p.Q388E | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.585); catalogued as rs1474592774, COSV100443400; called by muse, mutect2, varscan2
- COPA | c.1693G>C p.D565H | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99615876; called by muse, mutect2, varscan2
- CPA3 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.079); catalogued as rs867230201, COSV56045225; called by muse, mutect2, varscan2
- CR2 | c.2552G>A p.C851Y | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889658; called by muse, mutect2, varscan2
- CRIM1 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.965); catalogued as COSV54868671, COSV99753574; called by muse, mutect2, varscan2
- CSMD3 | c.5231del p.G1744Efs*49 (on ENST00000297405 / NM_001363185.1; = p.G1640Efs*49 on NM_052900.3) | Frame Shift Del (DEL) | VAF 76/262 reads (29%) | catalogued as COSV52146370, COSV99822288; called by mutect2, pindel, varscan2
- CTSZ | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99413432; called by muse, mutect2, varscan2
- CWC22 | c.2555C>G p.S852* | Nonsense Mutation (SNP) | VAF 19/108 reads (18%) | catalogued as COSV99844083, COSV99844335; called by muse, mutect2, varscan2
- CXCL12 | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 60/290 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1348700155, COSV100638951; called by muse, mutect2, varscan2
- DCBLD1 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 40/112 reads (36%) | catalogued as rs1186229621, COSV99757699; called by muse, mutect2, varscan2
- DCLRE1A | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 72/307 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV100800387; called by muse, mutect2, varscan2
- DCST2 | c.350C>A p.T117N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99791997; called by muse, mutect2, varscan2
- DFFB | c.710C>G p.S237* | Nonsense Mutation (SNP) | VAF 28/96 reads (29%) | catalogued as COSV100138712, COSV58860672; called by muse, mutect2, varscan2
- DGCR8 | c.1596C>G p.F532L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV100707998, COSV61226317; called by muse, mutect2, varscan2
- DHRS7 | c.973-1G>A p.X325_splice | Splice Site (SNP) | VAF 24/119 reads (20%) | catalogued as COSV99381626; called by muse, mutect2, varscan2
- DIO2 | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); catalogued as COSV101375894; called by muse, mutect2, varscan2
- DNAH12 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100244584, COSV60857296; called by muse, mutect2, varscan2
- DNAH5 | c.3625G>A p.E1209K | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV54263582; called by muse, mutect2, varscan2
- DSN1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.9); catalogued as rs763993322, COSV101041056; called by muse, mutect2, varscan2
- DZIP1L | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs987675067, COSV59521667; called by muse, mutect2, varscan2
- EBF1 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100565902; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1454462053, COSV100201095; called by muse, mutect2
- EIF4ENIF1 | c.715G>C p.D239H | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100349210; called by muse, mutect2, varscan2
- ELOVL4 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100876304; called by muse, mutect2, varscan2
- EMC4 | c.518G>C p.R173T | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV50784678, COSV99272275; called by muse, mutect2, varscan2
- EPHB3 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100383117; called by muse, mutect2, varscan2
- EPN1 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99321987; called by muse, mutect2, varscan2
- EPS15 | c.651G>T p.T217= | Splice Region (SNP) | VAF 34/152 reads (22%) | catalogued as rs1474368057, COSV100869555; called by muse, mutect2, varscan2
- EPS8L1 | c.502G>A p.A168T (on ENST00000201647 / NM_133180.3; = p.A41T on NM_017729.3) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.528); catalogued as rs763596957, COSV99136444; called by muse, mutect2, varscan2
- ERBB4 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as rs866040902, COSV53501755; called by muse, mutect2, varscan2
- ERICH3 | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.762); catalogued as rs757852992, COSV100444589; called by muse, mutect2, varscan2
- ERP44 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV99316481; called by muse, mutect2, varscan2
- ESF1 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.156); catalogued as COSV52524966; called by muse, mutect2, varscan2
- ESPN | c.1085C>G p.S362W | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100911471; called by muse, mutect2, varscan2
- ETV3L | c.894G>C p.E298D | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101485596; called by muse, mutect2
- EXO1 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as COSV100799581; called by muse, mutect2, varscan2
- EXOC1 | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1283559253, COSV100637899; called by muse, mutect2, varscan2
- EXOSC10 | c.1343A>G p.Y448C | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100442606; called by muse, mutect2, varscan2
- F5 | c.3835G>A p.D1279N | Missense Mutation (SNP) | VAF 80/474 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.08); catalogued as COSV100889130; called by muse, varscan2
- FAM47B | c.1842G>T p.K614N | Missense Mutation (SNP) | VAF 87/168 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV100264378; called by muse, mutect2, varscan2
- FANCG | c.1015C>A p.H339N | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as COSV100734233; called by muse, mutect2, varscan2
- FARP2 | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs746551418, COSV99884787; called by muse, mutect2, varscan2
- FBXO16 | c.237G>C p.E79D | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100672337; called by muse, mutect2, varscan2
- FCHO2 | c.1930G>C p.E644Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV100530771; called by muse, mutect2
- FHDC1 | c.3031G>C p.E1011Q | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV99471353; called by muse, mutect2, varscan2
- FLRT3 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.085); catalogued as COSV99428801; called by muse, mutect2, varscan2
- FMO1 | c.224C>A p.P75Q | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100707803; called by muse, mutect2, varscan2
- FOXM1 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV100700862; called by muse, mutect2, varscan2
- FOXRED2 | c.1741C>G p.L581V | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as COSV99340963; called by muse, mutect2, varscan2
- FRG1 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 54/681 reads (8%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.482); catalogued as rs1371484214, COSV56996289; called by muse, mutect2
- FRYL | c.6281C>G p.P2094R | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV99977114; called by muse, mutect2, varscan2
- FRYL | c.4070G>T p.G1357V | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99977116; called by muse, mutect2, varscan2
- FRYL | c.4069G>T p.G1357* | Nonsense Mutation (SNP) | VAF 41/170 reads (24%) | catalogued as COSV51952221, COSV99977118; called by muse, mutect2, varscan2
- FZD2 | c.1280G>A p.G427D | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59528334; called by muse, mutect2, varscan2
- GAS8 | c.1235C>G p.S412W | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs548463078, COSV99244020; called by muse, mutect2, varscan2
- GATA2 | c.1426G>A p.V476M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1161135105, COSV100351350; called by muse, mutect2, varscan2
- GCN1 | c.1091C>G p.S364* | Nonsense Mutation (SNP) | VAF 18/127 reads (14%) | catalogued as rs772153885, COSV100325406, COSV56105676; called by muse, mutect2, varscan2
- GIGYF1 | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99309535; called by muse, mutect2, varscan2
- GINS4 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs781762102, COSV99394563; called by muse, mutect2, varscan2
- GLIPR1L2 | c.348T>G p.I116M | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100248628; called by muse, mutect2, varscan2
- GNRHR | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99892205; called by muse, mutect2, varscan2
- GORAB | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100883834; called by muse, mutect2, varscan2
- GPAM | c.2233C>T p.P745S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV100788251; called by muse, mutect2, varscan2
- GPATCH8 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100132693; called by muse, mutect2, varscan2
- GPR15 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV99423784; called by muse, mutect2, varscan2
- GPR75 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.055); catalogued as rs748159475, COSV100766142; called by muse, mutect2, varscan2
- GRIN3B | c.1607C>G p.S536C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99312608; called by muse, mutect2, varscan2
- GTF3C1 | c.1389G>T p.E463D | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV100649481; called by muse, mutect2, varscan2
- HACL1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV100329620; called by muse, mutect2, varscan2
- HECTD1 | c.1271G>C p.R424T | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV101237409, COSV67945011; called by muse, mutect2, varscan2
- HELQ | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.305); catalogued as COSV99787802; called by muse, mutect2, varscan2
- HIVEP2 | c.5764G>A p.D1922N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV99173772; called by muse, mutect2, varscan2
- HM13 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.132); catalogued as rs761608092, COSV100159568; called by muse, mutect2, varscan2
- HMCN1 | c.13296G>A p.M4432I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV54928555, COSV99630319; called by muse, mutect2, varscan2
- HOXD3 | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.908); catalogued as rs1361097280, COSV99980212; called by muse, mutect2, varscan2
- HTRA4 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.495); catalogued as rs1187647352, COSV56761198; called by muse, mutect2, varscan2
- ICAM1 | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV99320885; called by muse, mutect2, varscan2
- IDI2 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV52988831; called by muse, mutect2, varscan2
- IGHMBP2 | c.873G>C p.Q291H | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as rs748408625, COSV99662146; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.336G>T p.M112I | Missense Mutation (SNP) | VAF 89/894 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs368282763; called by muse, mutect2, varscan2
- IL18RAP | c.982C>G p.Q328E | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.033); catalogued as COSV99962093; called by muse, mutect2, varscan2
- IL33 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs866491756, COSV67342871; called by muse, mutect2, varscan2
- ILDR2 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); catalogued as COSV99613047, COSV99613986; called by muse, mutect2, varscan2
- IMPA2 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 36/368 reads (10%) | catalogued as COSV99302598; called by muse, mutect2
- INMT | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.9); catalogued as COSV99185025; called by muse, mutect2, varscan2
- IPO4 | c.1892C>G p.S631C | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV100269074; called by muse, mutect2, varscan2
- IRF2BPL | c.92C>G p.S31W | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs1425872953, COSV99468190; called by muse, mutect2, varscan2
- ITGA8 | c.473C>G p.T158S | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV100959275, COSV65229200; called by muse, mutect2, varscan2
- ITIH5 | c.296C>A p.T99N | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99904856; called by muse, mutect2, varscan2
- IZUMO1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV99710848; called by muse, mutect2, varscan2
- JAG2 | c.2112G>A p.W704* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as rs1297570405, COSV100078491; called by muse, mutect2, varscan2
- JPH1 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 125/307 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as COSV100646640; called by muse, mutect2, varscan2
- KANK1 | c.2328G>A p.M776I | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV100619889; called by muse, mutect2, varscan2
- KIAA0586 | c.3626C>G p.S1209* (on ENST00000619416 / NM_001244190.2; = p.S1148* on NM_014749.5) | Nonsense Mutation (SNP) | VAF 15/103 reads (15%) | catalogued as COSV99708281; called by muse, mutect2, varscan2
- KIAA1522 | c.2540C>T p.S847L (on ENST00000373480 / NM_001198972.2; = p.S906L on NM_020888.3) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs776125780, COSV53864939; called by muse, mutect2
- KIAA2026 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as rs748673441, COSV52388503, COSV99035492; called by muse, mutect2, varscan2
- KIF27 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99927033; called by muse, mutect2, varscan2
- KIR2DL4 | c.739G>A p.D247N (on ENST00000396284; = p.D208N on NM_001080770.2) | Missense Mutation (SNP) | VAF 154/495 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs1272206087; called by muse, mutect2, varscan2
- KL | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 85/315 reads (27%) | catalogued as COSV101199070; called by muse, mutect2, varscan2
- KLF10 | c.1175C>T p.T392M | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760068758, COSV99574570; called by muse, mutect2
- KLHL9 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100757109; called by muse, mutect2, varscan2
- KRT3 | c.1106G>T p.S369I | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100527114; called by muse, mutect2, varscan2
- LAMA3 | c.1759G>C p.D587H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.072); catalogued as COSV100556996; called by muse, mutect2
- LCOR | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100603654; called by muse, mutect2, varscan2
- LENG1 | c.483G>T p.Q161H | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV99651956; called by muse, mutect2, varscan2
- LGR5 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99878016; called by muse, mutect2, varscan2
- LHX6 | c.721G>C p.D241H (on ENST00000373755 / NM_001242334.2; = p.D270H on NM_014368.5) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100493458; called by muse, mutect2, varscan2
- LIPE | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1233388425, COSV54925671; called by muse, mutect2, varscan2
- LMBRD2 | c.1933G>C p.E645Q | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.153); catalogued as COSV99682783, COSV99682909; called by muse, mutect2, varscan2
- LRFN5 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as COSV53246426, COSV99982062, COSV99984147; called by muse, mutect2, varscan2
- LRP1B | c.11527G>A p.E3843K | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.081); catalogued as COSV101257741; called by muse, mutect2, varscan2
- LRRC23 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs782816048, COSV99145222, COSV99145381; called by muse, mutect2
- LRRC37A3 | c.3397G>C p.D1133H | Missense Mutation (SNP) | VAF 100/379 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58535039, COSV58536353; called by muse, mutect2, varscan2
- LRRC7 | c.2317G>A p.D773N (on ENST00000651989 / NM_001370785.2; = p.D740N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); catalogued as COSV99227474; called by muse, mutect2, varscan2
- LRRCC1 | c.2989G>A p.E997K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100835481; called by muse, mutect2
- LSR | c.728C>G p.S243* | Nonsense Mutation (SNP) | VAF 33/117 reads (28%) | catalogued as COSV100670479; called by muse, mutect2, varscan2
- MACROD2 | c.862G>A p.E288K (on ENST00000642719; = p.E260K on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV54072569; called by muse, mutect2, varscan2
- MAGEC3 | c.696C>G p.F232L | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.168); catalogued as COSV100025537; called by muse, mutect2, varscan2
- MAP7 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 15/101 reads (15%) | catalogued as rs1474005117, COSV100643916; called by muse, mutect2, varscan2
- MCF2L2 | c.2329G>C p.D777H | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100192790; called by muse, mutect2, varscan2
- MDC1 | c.3166C>G p.Q1056E | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV100902410, COSV100902854; called by muse, mutect2, varscan2
- MFF | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 86/511 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as COSV100449342; called by muse, mutect2, varscan2
- MGAT2 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100023557; called by muse, mutect2, varscan2
- MGAT4C | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as COSV59837639; called by muse, mutect2
- MIA3 | c.4270C>G p.Q1424E | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV100485061; called by muse, mutect2, varscan2
- MIDEAS | c.2556C>G p.F852L | Missense Mutation (SNP) | VAF 36/399 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54096522; called by muse, mutect2
- MOB1B | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100511567, COSV58675594; called by muse, mutect2, varscan2
- MSGN1 | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99808771; called by muse, mutect2, varscan2
- MTBP | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1185537104, COSV100012214; called by muse, mutect2, varscan2
- MTUS2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV70915080; called by muse, mutect2, varscan2
- MUC15 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99846473; called by muse, mutect2, varscan2
- MUC16 | c.9659T>A p.I3220N | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV101200122; called by muse, mutect2, varscan2
- MUC17 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV100073701; called by muse, mutect2, varscan2
- MYBPC1 | c.1585C>G p.L529V (on ENST00000550270 / NM_206820.2; = p.L554V on NM_002465.4) | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.992); catalogued as COSV100638070; called by muse, mutect2, varscan2
- MYBPC1 | c.2518C>G p.R840G (on ENST00000550270 / NM_206820.2; = p.R847G on NM_002465.4) | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs768199021, COSV62251975; called by muse, mutect2, varscan2
- MYH3 | c.3316C>G p.Q1106E | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV99878315; called by muse, mutect2, varscan2
- MYH6 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs768924353, COSV100676153, COSV62451798; called by muse, mutect2, varscan2
- MYH7B | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370896124, COSV53418433; called by muse, mutect2, varscan2
- MYO7B | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101268227, COSV101268333; called by muse, mutect2, varscan2
- MYO7B | c.2717A>G p.Y906C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.887); catalogued as COSV101268228; called by muse, mutect2, varscan2
- NAV2 | c.2230G>T p.A744S (on ENST00000396087 / NM_001244963.2; = p.A721S on NM_145117.5) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.101); catalogued as COSV100586460; called by muse, mutect2, varscan2
- NCOR2 | c.6286G>A p.E2096K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100657423; called by muse, mutect2, varscan2
- NDFIP2 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV54530259; called by muse, mutect2, varscan2
- NEUROD2 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV100223147; called by muse, mutect2, varscan2
- NFRKB | c.811C>G p.Q271E (on ENST00000446488 / NM_001143835.2; = p.Q296E on NM_006165.3) | Missense Mutation (SNP) | VAF 80/247 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); catalogued as COSV100451939; called by muse, mutect2, varscan2
- NHLRC4 | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as rs1380268733, COSV99216159; called by muse, mutect2, varscan2
- NIPBL | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV99240920; called by muse, mutect2, varscan2
- NLN | c.799G>C p.A267P | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101114320; called by muse, mutect2, varscan2
- NR5A1 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as CD101676, COSV101007697; called by muse, mutect2
- NRK | c.3797C>T p.S1266L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99687488, COSV99688076; called by muse, mutect2, varscan2
- NSD1 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.437); catalogued as rs377471340; called by muse, mutect2, varscan2
- NTNG1 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV53964876, COSV99637837; called by muse, mutect2, varscan2
- NUCB2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV100082829; called by mutect2, varscan2
- NXPH1 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); catalogued as rs1274208163, COSV101339717; called by muse, mutect2, varscan2
- OAS2 | c.2039G>T p.W680L | Missense Mutation (SNP) | VAF 58/450 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60802391, COSV60804741; called by muse, mutect2, varscan2
- OAS3 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377096533; called by muse, mutect2, varscan2
- OPRK1 | c.113G>C p.S38T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV99654136; called by muse, mutect2, varscan2
- OPRM1 | c.1105C>A p.R369S | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV100001511, COSV57674181; called by muse, mutect2, varscan2
- OR10Z1 | c.170C>G p.T57S | Missense Mutation (SNP) | VAF 100/425 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV100779031; called by muse, mutect2, varscan2
- OR2B3 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV101013799; called by muse, mutect2, varscan2
- OR2T35 | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100442295; called by mutect2, varscan2
- ORC2 | c.246G>C p.L82F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.289); catalogued as COSV99309582; called by muse, mutect2, varscan2
- OTOGL | c.3578C>G p.S1193* (on ENST00000547103; = p.S1184* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/160 reads (16%) | catalogued as COSV101509336, COSV72007236; called by muse, mutect2, varscan2
- PATJ | c.5119G>T p.A1707S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as rs749949716, COSV100957214; called by muse, mutect2, varscan2
- PAX1 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767792155, COSV68273467; called by muse, mutect2, varscan2
- PCDHA6 | c.1615G>T p.D539Y | Missense Mutation (SNP) | VAF 83/346 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100971530, COSV65348503; called by muse, mutect2, varscan2
- PCNX2 | c.2439C>G p.I813M | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.646); catalogued as COSV99268060, COSV99270265; called by muse, mutect2, varscan2
- PCNX3 | c.4133C>G p.S1378C | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100856467; called by muse, mutect2, varscan2
- PCSK2 | c.422C>A p.T141N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.093); catalogued as COSV99359794; called by muse, mutect2
- PDCL3 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs750616995, COSV51809826; called by muse, mutect2, varscan2
- PDE11A | c.2542G>C p.E848Q | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.607); catalogued as COSV99612802; called by muse, mutect2, varscan2
- PDE3B | c.1086G>T p.M362I | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV99962673; called by muse, mutect2, varscan2
- PDLIM5 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs778323849, COSV100523807; called by muse, mutect2, varscan2
- PDZD2 | c.8473G>C p.E2825Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99225348; called by muse, mutect2, varscan2
- PDZRN3 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 77/291 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.666); catalogued as COSV99730088; called by muse, mutect2, varscan2
- PER3 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | catalogued as COSV100728371, COSV62706829; called by muse, mutect2, varscan2
- PHF14 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.271); catalogued as COSV101301815; called by muse, mutect2, varscan2
- PHF3 | c.449C>G p.S150* | Nonsense Mutation (SNP) | VAF 79/284 reads (28%) | catalogued as COSV100012794; called by muse, mutect2, varscan2
- PIGN | c.2081C>T p.S694F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV62949507, COSV62949540; called by muse, mutect2, varscan2
- PIK3AP1 | c.1864G>A p.V622M | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV100225850; called by muse, mutect2, varscan2
- PLBD2 | c.705C>G p.I235M | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs1299738077, COSV99785356; called by muse, mutect2, varscan2
- PLD5 | c.973G>C p.D325H (on ENST00000442594; = p.D263H on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100140721, COSV59173237; called by muse, mutect2, varscan2
- PNRC1 | c.175C>G p.H59D | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.215); catalogued as COSV100259933; called by muse, mutect2, varscan2
- POU2F1 | c.157C>G p.Q53E (on ENST00000541643 / NM_001365848.1; = p.Q76E on NM_002697.4) | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.585); catalogued as COSV99611288; called by muse, mutect2
- PPP1CC | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100534886; called by muse, mutect2, varscan2
- PPP1R12A | c.1047G>C p.K349N | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV99700445; called by muse, mutect2, varscan2
- PPP1R13B | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV99159534; called by muse, mutect2, varscan2
- PPP1R3D | c.810C>G p.N270K | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100674558; called by muse, mutect2, varscan2
- PRKDC | c.2632G>T p.E878* | Nonsense Mutation (SNP) | VAF 44/130 reads (34%) | catalogued as rs1319344777, COSV100041008; called by muse, mutect2, varscan2
- PRMT1 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as rs1285474650, COSV101212288; called by muse, mutect2, varscan2
- PRPF38A | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV57123410, COSV99933322; called by muse, mutect2, varscan2
- PRPF40B | c.2230G>A p.E744K (on ENST00000380281; = p.E731K on NM_012272.3) | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.034); catalogued as COSV99526426; called by muse, mutect2, varscan2
- PSG6 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 171/702 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV99414133; called by muse, varscan2
- PSMD2 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100031822, COSV100031823; called by muse, mutect2, varscan2
- PTPRH | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 58/341 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.652); catalogued as COSV54749143, COSV99671088; called by muse, mutect2, varscan2
- RAB11FIP4 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1303907139, COSV57928705; called by muse, mutect2, varscan2
- RAD51AP1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.056); catalogued as COSV99961315; called by muse, mutect2, varscan2
- RAPGEF2 | c.3497C>A p.S1166* | Nonsense Mutation (SNP) | VAF 23/120 reads (19%) | catalogued as COSV52428856; called by muse, mutect2, varscan2
- RBL2 | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100043423, COSV100043717; called by muse, mutect2, varscan2
- RBMXL1 | c.1166G>C p.R389T | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV99556379; called by muse, mutect2, varscan2
- RCN2 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100312789; called by muse, mutect2, varscan2
- RELCH | c.3460G>T p.V1154F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV99902220; called by muse, mutect2, varscan2
- RELN | c.2466-1G>T p.X822_splice | Splice Site (SNP) | VAF 25/81 reads (31%) | catalogued as rs1442404996, COSV100633950, COSV58999315; called by muse, mutect2, varscan2
- RFC4 | c.974C>G p.S325C | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV99961243, COSV99961450; called by muse, mutect2, varscan2
- RGS11 | c.1177C>T p.Q393* (on ENST00000397770 / NM_183337.3; = p.Q372* on NM_003834.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99395842; called by muse, mutect2, varscan2
- RGS22 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 45/271 reads (17%) | catalogued as rs932703758, COSV100693330, COSV62665175; called by muse, mutect2, varscan2
- RIMS2 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.171); catalogued as COSV101267319, COSV68113179; called by muse, mutect2
- RIPOR1 | c.1408G>A p.E470K (on ENST00000379312 / NM_001193522.2; = p.E466K on NM_024519.4) | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99243205; called by muse, mutect2, varscan2
- RIPOR3 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV50385525; called by muse, mutect2, varscan2
- RNF111 | c.878C>G p.S293* | Nonsense Mutation (SNP) | VAF 49/108 reads (45%) | catalogued as COSV100789082; called by muse, mutect2, varscan2
- RNF141 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV99792929, COSV99793058; called by muse, mutect2
- RNF157 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99487069; called by muse, mutect2, varscan2
- RRP36 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 82/390 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1369251295, COSV99763788; called by muse, varscan2
- RSL1D1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 27/64 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100851990, COSV100852018; called by muse, mutect2, varscan2
- RTEL1 | c.2349C>A p.F783L | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs200068703, COSV100542415; called by muse, mutect2, varscan2
- RTN1 | c.2017C>T p.Q673* | Nonsense Mutation (SNP) | VAF 12/138 reads (9%) | catalogued as COSV99955868; called by muse, mutect2
- RTN4IP1 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV100954197; called by muse, mutect2, varscan2
- SALL1 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1388841718, COSV99174474; called by muse, mutect2, varscan2
- SASH3 | c.592-1G>A p.X198_splice | Splice Site (SNP) | VAF 68/130 reads (52%) | catalogued as COSV100795240; called by muse, mutect2, varscan2
- SCAMP2 | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 105/285 reads (37%) | catalogued as COSV51510435; called by muse, mutect2, varscan2
- SCN3A | c.5371G>A p.E1791K | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99327283; called by muse, mutect2, varscan2
- SEC23A | c.1519C>G p.Q507E | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.028); catalogued as COSV100305551; called by muse, mutect2, varscan2
- SENP1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1487983284, COSV99136973; called by muse, mutect2
- SERPINA9 | c.953T>A p.L318Q | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100098452; called by muse, mutect2, varscan2
- SETBP1 | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.372); catalogued as rs867162561, COSV99953596; called by muse, mutect2, varscan2
- SETDB2 | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.108); catalogued as rs1273692027, COSV99320818; called by muse, mutect2, varscan2
- SETX | c.3691G>A p.E1231K | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99809999; called by muse, mutect2, varscan2
- SETX | c.3124G>C p.E1042Q | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV99810002; called by muse, mutect2, varscan2
- SI | c.3576G>C p.L1192F | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100015824, COSV52306102; called by muse, mutect2, varscan2
- SIGIRR | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100230104; called by muse, mutect2, varscan2
- SLC19A2 | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs867139297, COSV99356990; called by muse, mutect2
- SLC25A13 | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 62/417 reads (15%) | catalogued as rs540149539, CM103907, COSV99673732; called by muse, mutect2, varscan2
- SLC35G2 | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 48/239 reads (20%) | catalogued as COSV101262040; called by muse, mutect2, varscan2
- SLC39A3 | c.585G>C p.E195D | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99514217; called by muse, mutect2, varscan2
- SLC8A3 | c.1321A>G p.N441D | Missense Mutation (SNP) | VAF 32/321 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100776242; called by muse, mutect2, varscan2
- SMARCC2 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); catalogued as COSV99911434; called by muse, mutect2, varscan2
- SMG8 | c.963G>C p.Q321H | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs371370396; called by muse, mutect2, varscan2
- SNED1 | c.234C>G p.I78M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs1334327107, COSV100122802; called by muse, mutect2, varscan2
- SNX13 | c.531G>C p.Q177H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.537); catalogued as rs1258365598, COSV101285116; called by muse, mutect2, varscan2
- SOX6 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100322364; called by muse, mutect2, varscan2
- SPINDOC | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 104/218 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs759066744, COSV99588692; called by muse, mutect2, varscan2
- SPOCK1 | c.470C>G p.S157C | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1287916820, COSV99969607; called by muse, mutect2, varscan2
- SPTBN4 | c.343A>T p.M115L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV100151119; called by muse, mutect2, varscan2
- SPTBN5 | c.3281G>A p.R1094Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1275574162, COSV100311589; called by muse, mutect2, varscan2
- SS18L1 | c.366G>C p.Q122H | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.916); catalogued as COSV100064985; called by muse, mutect2, varscan2
- SSR3 | c.60C>A p.F20L | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.167); catalogued as rs1334467778, COSV54020051, COSV99411131; called by muse, mutect2, varscan2
- STAB2 | c.7135C>A p.H2379N | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV101186036; called by muse, mutect2, varscan2
- STAT1 | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.088); catalogued as COSV100738686; called by muse, mutect2, varscan2
- STYXL2 | c.1644G>C p.K548N | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99609368; called by muse, mutect2, varscan2
- SULT1C2 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as rs1223825559, COSV99265232; called by muse, mutect2, varscan2
- SVEP1 | c.3973C>A p.Q1325K | Missense Mutation (SNP) | VAF 118/272 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.093); catalogued as COSV100238209; called by muse, mutect2, varscan2
- SYNE1 | c.4592G>A p.R1531K (on ENST00000367255 / NM_182961.4; = p.R1538K on NM_033071.3) | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV99567081; called by muse, mutect2, varscan2
- SYNE2 | c.12149A>G p.N4050S | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100647849; called by muse, mutect2, varscan2
- SYNE2 | c.18494C>T p.S6165L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV100647850; called by muse, mutect2, varscan2
- SYTL1 | c.784G>A p.E262K (on ENST00000543823; = p.E250K on NM_032872.3) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs1218195047, COSV100539375; called by muse, mutect2, varscan2
- TAGLN2 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 83/510 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV100231177; called by muse, mutect2, varscan2
- TBC1D8 | c.629G>C p.R210T | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100964509; called by muse, mutect2, varscan2
- TBK1 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100538198; called by muse, mutect2, varscan2
- TCEAL2 | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1334856266, COSV100216333; called by muse, mutect2, varscan2
- TDRD1 | c.2975G>C p.R992T | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.426); catalogued as COSV99314641; called by muse, mutect2, varscan2
- TDRD10 | c.87C>G p.F29L | Missense Mutation (SNP) | VAF 19/239 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100873124; called by muse, mutect2
- TFDP2 | c.337G>A p.D113N (on ENST00000489671 / NM_001178139.2; = p.D52N on NM_006286.5) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV100050985; called by muse, mutect2, varscan2
- TG | c.5138C>T p.S1713L | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99601306; called by muse, mutect2, varscan2
- THBS1 | c.2886G>A p.M962I | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as COSV99528007; called by muse, mutect2, varscan2
- TIMP2 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.929); catalogued as rs1410997894, COSV53160768; called by muse, mutect2
- TLR2 | c.810G>A p.M270I | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99472360; called by muse, mutect2, varscan2
- TLR4 | c.2126A>G p.Y709C (on ENST00000355622 / NM_138554.5; = p.Y669C on NM_003266.4) | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs377719663, COSV100842777; called by muse, mutect2, varscan2
- TMEM131L | c.2545C>G p.L849V | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99547584; called by muse, mutect2, varscan2
- TMTC3 | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs748664360, COSV99898409; called by muse, mutect2, varscan2
- TPP2 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV101060295; called by muse, mutect2, varscan2
- TPPP2 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 18/159 reads (11%) | catalogued as COSV100409572; called by muse, mutect2, varscan2
- TPST1 | c.59C>G p.T20S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.067); catalogued as COSV100507149; called by muse, mutect2, varscan2
- TRERF1 | c.3493G>A p.D1165N | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.238); catalogued as rs769439387, COSV61674127; called by muse, mutect2, varscan2
- TRIM62 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.724); catalogued as COSV99357823; called by mutect2, varscan2
- TRIO | c.6024G>C p.M2008I | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.071); catalogued as COSV100709729, COSV100710467; called by muse, mutect2, varscan2
- TRIP4 | c.1471C>G p.L491V | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV56029327; called by muse, mutect2, varscan2
- TRMT10A | c.53del p.K18Sfs*4 | Frame Shift Del (DEL) | VAF 16/114 reads (14%) | catalogued as rs747549755; called by mutect2, pindel, varscan2
- TRNT1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.205); catalogued as rs780260411, COSV99285757; called by muse, mutect2, varscan2
- TSC2 | c.2974C>T p.Q992* | Nonsense Mutation (SNP) | VAF 39/222 reads (18%) | catalogued as rs45438592, CM981951, COSV99554343; ClinVar: not provided; called by muse, mutect2, varscan2
- TTC17 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 84/470 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99235429; called by muse, mutect2, varscan2
- TTC27 | c.1237C>T p.L413F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100513154; called by muse, mutect2, varscan2
- TTN | c.64990G>C p.D21664H (on ENST00000591111; = p.D14240H on NM_003319.4) | Missense Mutation (SNP) | VAF 25/110 reads (23%) | PolyPhen benign (0.001); catalogued as COSV100616664, COSV60045919; called by muse, mutect2, varscan2
- TUBGCP3 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV99996947; called by muse, mutect2, varscan2
- UBAP2 | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 52/239 reads (22%) | catalogued as COSV100671530, COSV100672031; called by muse, mutect2, varscan2
- UBAP2L | c.2951C>T p.S984F | Missense Mutation (SNP) | VAF 46/685 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99671470; called by muse, mutect2
- UBE2C | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99708633; called by muse, mutect2, varscan2
- UBE2E3 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.487); catalogued as COSV101150421, COSV101150714; called by muse, mutect2, varscan2
- UBE4B | c.2103C>G p.I701M (on ENST00000343090 / NM_001105562.3; = p.I572M on NM_006048.5) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53534985, COSV99476847; called by muse, mutect2, varscan2
- UGT8 | c.114C>A p.F38L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV100179237; called by muse, mutect2, varscan2
- USH2A | c.28T>C p.S10P | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs780210186, COSV100236300; called by muse, mutect2, varscan2
- USP20 | c.731A>G p.H244R | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100204393; called by muse, mutect2, varscan2
- USP47 | c.4045C>T p.R1349C (on ENST00000399455 / NM_001372095.1; = p.R1261C on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs371170010; called by muse, mutect2, varscan2
- USP9Y | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 40/132 reads (30%) | catalogued as rs888918343, COSV100168365; called by muse, mutect2, varscan2
- VANGL2 | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.214); catalogued as COSV100925594, COSV63604461; called by muse, mutect2
- VCL | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0.149); catalogued as COSV99280926; called by muse, mutect2
- VCP | c.1357del p.R453Gfs*4 | Frame Shift Del (DEL) | VAF 121/613 reads (20%) | catalogued as COSV62722524; called by mutect2, pindel, varscan2
- VPS54 | c.2203G>C p.E735Q | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV55444398, COSV99708221; called by muse, mutect2, varscan2
- WNT8A | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.844); catalogued as COSV100843056, COSV64230931; called by muse, mutect2, varscan2
- XRCC6 | c.1672G>C p.E558Q | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV100777847; called by muse, mutect2, varscan2
- YARS1 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 120/761 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100993438; called by muse, mutect2, varscan2
- ZAN | c.6178A>C p.T2060P | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as COSV100769813; called by muse, mutect2, varscan2
- ZBTB38 | c.3235G>A p.E1079K | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV100375692; called by muse, mutect2, varscan2
- ZBTB5 | c.467C>G p.S156* | Nonsense Mutation (SNP) | VAF 19/188 reads (10%) | catalogued as COSV100312797; called by muse, mutect2
- ZC3H14 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99193082; called by muse, mutect2, varscan2
- ZC3H7A | c.2213+2T>C p.X738_splice | Splice Site (SNP) | VAF 21/117 reads (18%) | catalogued as COSV100865539; called by muse, mutect2, varscan2
- ZDBF2 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100984981; called by muse, mutect2, varscan2
- ZFP69B | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV100848268; called by muse, mutect2, varscan2
- ZNF135 | c.547G>A p.E183K (on ENST00000313434 / NM_001289401.2; = p.E195K on NM_003436.4) | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.201); catalogued as rs768046446, COSV100536641; called by muse, mutect2, varscan2
- ZNF148 | c.2300C>T p.S767L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs968420508, COSV62303922; called by muse, mutect2, varscan2
- ZNF202 | c.38G>T p.W13L | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); catalogued as COSV100279064; called by muse, mutect2, varscan2
- ZNF221 | c.1402C>T p.H468Y | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52111145; called by muse, mutect2, varscan2
- ZNF230 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767743066, COSV101432011, COSV71273566; called by muse, mutect2, varscan2
- ZNF324 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1448356263, COSV99543338; called by muse, mutect2, varscan2
- ZNF418 | c.1678C>T p.H560Y | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375998081; called by muse, mutect2, varscan2
- ZNF45 | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV54192891, COSV99524166; called by muse, mutect2, varscan2
- ZNF507 | c.2403G>C p.L801F | Missense Mutation (SNP) | VAF 70/287 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100321884; called by muse, mutect2, varscan2
- ZNF574 | c.1054G>C p.D352H | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV99726194; called by muse, mutect2, varscan2
- ZNF575 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs745764744, COSV58564377, COSV58564609; called by muse, mutect2
- ZNF576 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.448); catalogued as COSV100338172; called by muse, mutect2, varscan2
- ZNF688 | c.304C>G p.R102G | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as COSV99794249; called by muse, mutect2
- ZNF7 | c.932G>A p.C311Y | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773588606, COSV100295911; called by muse, mutect2, varscan2
- ZNF763 | c.258G>T p.Q86H (on ENST00000358987 / NM_001367172.2; = p.Q89H on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.172); catalogued as COSV100676134; called by muse, mutect2, varscan2
- ZNF766 | c.63G>C p.E21D | Missense Mutation (SNP) | VAF 103/377 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100765362; called by muse, mutect2, varscan2
- ZNF831 | c.3018G>C p.E1006D | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV100926068; called by muse, mutect2, varscan2
- ZNRF4 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 76/261 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs541728675, COSV99706564; called by muse, mutect2, varscan2
- CWC25 | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- FASTKD3 | c.80dup p.N27Kfs*2 | Frame Shift Ins (INS) | VAF 14/116 reads (12%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.482G>C p.R161T | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GGNBP2 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 29/297 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2
- GPT2 | c.1175dup p.V393Gfs*8 | Frame Shift Ins (INS) | VAF 21/185 reads (11%) | called by mutect2, pindel, varscan2
- LILRB3 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MRC1 | c.3590G>C p.G1197A | Missense Mutation (SNP) | VAF 73/644 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- OPN1MW | c.747G>C p.V249= | Splice Region (SNP) | VAF 9/18 reads (50%) | called by mutect2, varscan2
- OR4N2 | c.215_216del p.S72Lfs*49 | Frame Shift Del (DEL) | VAF 108/598 reads (18%) | called by mutect2, varscan2
- RAB3GAP2 | c.4142_4161del p.L1381Hfs*14 | Frame Shift Del (DEL) | VAF 31/151 reads (21%) | called by mutect2, pindel, varscan2
- ACO2 | c.1455G>A p.E485= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as rs1237483884, COSV99347476; called by muse, mutect2, varscan2
- ACSL1 | c.1170G>A p.L390= | Silent (SNP) | VAF 32/241 reads (13%) | catalogued as COSV99860698; called by muse, mutect2
- ACTR3B | c.1047C>T p.L349= | Silent (SNP) | VAF 44/146 reads (30%) | catalogued as rs146208789; called by muse, mutect2, varscan2
- ADAT3 | c.228G>A p.L76= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100280280; called by muse, mutect2
- AGBL1 | c.2721G>A p.K907= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV101223314; called by muse, mutect2, varscan2
- ALDOA | c.813G>C p.L271= (on ENST00000642816 / NM_001243177.4; = p.L217= on NM_184041.5) | Silent (SNP) | VAF 38/193 reads (20%) | catalogued as rs772297021, COSV100582108; called by muse, mutect2, varscan2
- AQR | c.3480G>T p.V1160= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV99334067; called by muse, mutect2, varscan2
- ARHGEF19 | c.2232G>A p.V744= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV99580525; called by muse, mutect2, varscan2
- ARSJ | c.1209C>T p.I403= | Silent (SNP) | VAF 56/217 reads (26%) | catalogued as COSV100192778; called by muse, mutect2, varscan2
- BAD | c.420G>A p.Q140= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as rs368322510; called by muse, mutect2, varscan2
- BAG6 | c.3252C>T p.L1084= (on ENST00000676571; = p.L1037= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV99277161; called by muse, mutect2, varscan2
- BCAN | c.2184A>C p.T728= | Silent (SNP) | VAF 39/133 reads (29%) | catalogued as COSV100228174; called by muse, mutect2, varscan2
- BPTF | c.5103C>T p.V1701= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as COSV100075121; called by muse, mutect2
- CACNA2D4 | c.2679C>T p.I893= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs374453274; called by muse, mutect2, varscan2
- CBS | c.414C>T p.P138= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs201860288, COSV100657951; called by muse, mutect2, varscan2
- CCNB3 | c.3153C>G p.P1051= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV99328687, COSV99329215; called by muse, mutect2, varscan2
- CD177 | c.753A>T p.L251= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1406112618, COSV100945976; called by muse, mutect2
- CD180 | c.414C>A p.S138= | Silent (SNP) | VAF 36/240 reads (15%) | catalogued as COSV99842275; called by muse, mutect2, varscan2
- CD4 | c.228G>A p.L76= | Silent (SNP) | VAF 93/407 reads (23%) | catalogued as COSV50596877; called by muse, mutect2, varscan2
- CEP83 | c.210C>T p.L70= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs777598525, COSV100352901; called by muse, mutect2, varscan2
- CHD3 | c.1251A>G p.K417= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as COSV100391284, COSV57880318; called by muse, mutect2, varscan2
- CHN1 | c.813G>A p.T271= | Silent (SNP) | VAF 31/188 reads (16%) | catalogued as rs199663916, COSV55036596; called by muse, mutect2, varscan2
- CHRNA2 | c.783C>T p.I261= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV99532282; called by muse, mutect2, varscan2
- CHST9 | c.1146G>A p.Q382= | Silent (SNP) | VAF 49/225 reads (22%) | catalogued as COSV99410259; called by muse, mutect2, varscan2
- CMTR1 | c.987G>A p.G329= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as COSV100990880; called by muse, mutect2, varscan2
- COL6A3 | c.2116C>T p.L706= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV99798800; called by muse, mutect2, varscan2
- CRYGS | c.228C>G p.L76= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV100330001; called by muse, mutect2, varscan2
- CUX2 | c.1062G>A p.E354= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as rs1392625145, COSV99919873; called by muse, mutect2, varscan2
- DCLRE1A | c.2403C>T p.L801= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV100800385; called by muse, mutect2, varscan2
- DDB2 | c.888C>T p.F296= | Silent (SNP) | VAF 36/240 reads (15%) | catalogued as rs1190260071, COSV99921669; called by muse, mutect2, varscan2
- DNAAF2 | c.1611C>T p.L537= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100024130; called by muse, mutect2
- DNAH11 | c.5907C>T p.I1969= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100179463; called by muse, mutect2, varscan2
- DOCK7 | c.6369C>T p.V2123= (on ENST00000635253 / NM_001367561.1; = p.V2092= on NM_033407.3) | Silent (SNP) | VAF 37/138 reads (27%) | catalogued as COSV99224756; called by muse, mutect2, varscan2
- DYNC1H1 | c.8496C>A p.L2832= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV100795005; called by muse, mutect2
- DYNC2H1 | c.8757A>G p.G2919= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100518744; called by mutect2, varscan2
- EPHB4 | c.576C>T p.L192= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs1427578173, COSV100639521; called by muse, mutect2, varscan2
- ERAP1 | c.228C>T p.F76= | Silent (SNP) | VAF 50/172 reads (29%) | catalogued as COSV99701004; called by muse, mutect2, varscan2
- ETV3 | c.21C>T p.I7= | Silent (SNP) | VAF 82/462 reads (18%) | catalogued as rs1007124749, COSV100461084; called by muse, varscan2
- FAM120C | c.501C>G p.L167= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100070159; called by muse, mutect2, varscan2
- FANCF | c.258C>G p.L86= | Silent (SNP) | VAF 26/176 reads (15%) | catalogued as COSV59416996; called by muse, mutect2, varscan2
- FEZ1 | c.351C>G p.L117= | Silent (SNP) | VAF 61/206 reads (30%) | catalogued as COSV99630732; called by muse, mutect2, varscan2
- FGD1 | c.2619C>T p.F873= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as rs375328916, COSV64308336; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- FOXL2 | c.258G>A p.A86= | Silent (SNP) | VAF 33/207 reads (16%) | catalogued as rs1487527950, COSV100374601; called by muse, mutect2, varscan2
- FRYL | c.7881G>A p.L2627= | Silent (SNP) | VAF 39/157 reads (25%) | catalogued as COSV51953140; called by muse, mutect2, varscan2
- GAS2L2 | c.2265G>A p.L755= | Silent (SNP) | VAF 69/259 reads (27%) | called by muse, mutect2, varscan2
- GINS4 | c.219G>A p.L73= | Silent (SNP) | VAF 57/110 reads (52%) | catalogued as rs560085005, COSV99394558; called by muse, mutect2, varscan2
- H6PD | c.2205C>A p.L735= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as COSV101072490; called by muse, mutect2, varscan2
- HAUS3 | c.150G>A p.Q50= | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as rs759132380, COSV99704289; called by muse, mutect2, varscan2
- HECTD4 | c.11952G>A p.V3984= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV101107725; called by muse, mutect2, varscan2
- HERC2 | c.2007C>T p.S669= | Silent (SNP) | VAF 56/143 reads (39%) | catalogued as COSV99874357; called by muse, mutect2, varscan2
- HIVEP2 | c.5997G>A p.Q1999= | Silent (SNP) | VAF 66/293 reads (23%) | catalogued as COSV99173767; called by muse, mutect2, varscan2
- HSPG2 | c.9264C>G p.T3088= | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as rs201662778, COSV101013480, COSV65933159; called by muse, mutect2, varscan2
- ICA1L | c.573G>A p.V191= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs942036515, COSV100841772, COSV100841795; called by muse, mutect2, varscan2
- IGFALS | c.309C>G p.L103= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99236553; called by muse, mutect2
- INTS3 | c.3128G>A p.*1043= | Silent (SNP) | VAF 31/266 reads (12%) | catalogued as COSV99669970; called by muse, mutect2, varscan2
- ITGAL | c.1035C>T p.F345= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as COSV100776276; called by muse, mutect2, varscan2
- ITLN2 | c.537G>A p.L179= | Silent (SNP) | VAF 27/256 reads (11%) | catalogued as COSV100600722; called by muse, mutect2, varscan2
- KCNH7 | c.2748C>A p.T916= | Silent (SNP) | VAF 32/173 reads (18%) | catalogued as COSV100148258; called by muse, mutect2, varscan2
- KCNS2 | c.342C>T p.F114= | Silent (SNP) | VAF 40/191 reads (21%) | catalogued as COSV99751212; called by muse, mutect2, varscan2
- KIF20A | c.1119C>G p.L373= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as COSV99137086; called by muse, mutect2, varscan2
- KIF4B | c.822C>T p.I274= | Silent (SNP) | VAF 22/198 reads (11%) | catalogued as COSV101469297; called by muse, mutect2, varscan2
- KMT2D | c.14982G>T p.L4994= | Silent (SNP) | VAF 17/147 reads (12%) | catalogued as rs1325810003, COSV99982718; called by muse, mutect2, varscan2
- KRT19 | c.87C>T p.V29= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV64239058; called by muse, mutect2, varscan2
- KRT74 | c.681G>A p.K227= | Silent (SNP) | VAF 11/178 reads (6%) | catalogued as rs781291481, COSV99977558; called by muse, mutect2
- LAMA5 | c.819C>T p.L273= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV53369240, COSV99440424; called by muse, mutect2, varscan2
- LRRCC1 | c.1405C>T p.L469= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as rs746837360, COSV100835480; called by muse, mutect2, varscan2
- MAML1 | c.979C>T p.L327= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV52988565; called by muse, mutect2, varscan2
- MARS2 | c.21C>T p.L7= | Silent (SNP) | VAF 18/137 reads (13%) | catalogued as rs925365571, COSV99986603; called by muse, mutect2, varscan2
- MDC1 | c.345G>C p.L115= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV100902855, COSV64526555; called by muse, mutect2, varscan2
- METAP1D | c.57C>T p.F19= | Silent (SNP) | VAF 47/270 reads (17%) | catalogued as rs764314956, COSV59932073; called by muse, mutect2, varscan2
- MIA3 | c.4329G>T p.R1443= | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as COSV100485064; called by muse, mutect2, varscan2
- MITD1 | c.18G>C p.L6= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV56806966; called by muse, mutect2, varscan2
- MSR1 | c.432C>T p.F144= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV100027430; called by muse, mutect2, varscan2
- MTHFR | c.414C>T p.I138= | Silent (SNP) | VAF 53/220 reads (24%) | catalogued as COSV100411989; called by muse, mutect2, varscan2
- MVB12A | c.486C>G p.L162= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV100396522; called by muse, mutect2, varscan2
- MXRA5 | c.6447G>C p.T2149= | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as rs760712668, COSV54246387, COSV99477297; called by muse, mutect2, varscan2
- MYH13 | c.4602G>A p.K1534= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as COSV99354244; called by muse, mutect2, varscan2
- MYH7 | c.3123G>A p.E1041= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV100806196; called by muse, mutect2, varscan2
- MYOM3 | c.4221C>G p.V1407= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV100141772; called by muse, mutect2
- NCAN | c.3837G>A p.R1279= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV99387424; called by muse, mutect2, varscan2
- NDC1 | c.1146C>G p.L382= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as rs202146843; called by muse, mutect2, varscan2
- NELFCD | c.978C>T p.F326= (on ENST00000602795; = p.F308= on NM_198976.4) | Silent (SNP) | VAF 35/182 reads (19%) | catalogued as rs368566687, COSV99413611; called by muse, mutect2, varscan2
- NES | c.378G>C p.L126= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100957887, COSV63962421; called by muse, mutect2
- NRP1 | c.1701G>A p.E567= | Silent (SNP) | VAF 60/331 reads (18%) | catalogued as COSV99588894; called by muse, mutect2, varscan2
- NRXN3 | c.2451C>A p.I817= (on ENST00000335750 / NM_001330195.2; = p.I444= on NM_004796.6) | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as rs944771134, COSV100204533; called by muse, mutect2, varscan2
- NSUN3 | c.798G>A p.T266= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs757041028, COSV100113313; called by muse, mutect2, varscan2
- NTRK2 | c.1119G>A p.Q373= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV99455767; called by muse, mutect2, varscan2
- OR1J2 | c.582C>G p.L194= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as COSV100093270; called by muse, mutect2, varscan2
- OR2Y1 | c.313C>T p.L105= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV100322778; called by muse, mutect2, varscan2
- PCDHA5 | c.2076G>T p.L692= | Silent (SNP) | VAF 51/156 reads (33%) | catalogued as rs1554129633, COSV100972342; called by muse, mutect2, varscan2
- PCDHB4 | c.633C>T p.L211= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as COSV52019723; called by muse, mutect2, varscan2
- PCDHGA4 | c.447G>A p.R149= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV99539833; called by muse, mutect2, varscan2
- PDE6C | c.1638C>G p.T546= | Silent (SNP) | VAF 46/192 reads (24%) | catalogued as COSV101008775; called by muse, mutect2, varscan2
- PHF21A | c.1278G>A p.R426= (on ENST00000418153 / NM_001101802.3; = p.R427= on NM_016621.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 24/238 reads (10%) | catalogued as rs988086483, COSV99138634; called by muse, mutect2
- PHLDB2 | c.1530G>A p.R510= | Silent (SNP) | VAF 44/276 reads (16%) | catalogued as COSV101208556; called by muse, mutect2, varscan2
- POLG2 | c.150C>T p.L50= | Silent (SNP) | VAF 41/239 reads (17%) | catalogued as rs1202762031, COSV99858037; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPIP5K1 | c.3582C>T p.F1194= (on ENST00000396923; = p.F1169= on NM_014659.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 49/120 reads (41%) | catalogued as COSV100288719; called by muse, mutect2, varscan2
- PRDM15 | c.1215G>A p.Q405= | Silent (SNP) | VAF 32/150 reads (21%) | catalogued as COSV99520238; called by muse, mutect2, varscan2
- PRELID3B | c.195G>A p.V65= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV100582263; called by muse, mutect2, varscan2
- PRKACG | c.750G>A p.K250= | Silent (SNP) | VAF 13/164 reads (8%) | catalogued as COSV99599026; called by muse, mutect2
- RAB11FIP5 | c.708C>G p.L236= | Silent (SNP) | VAF 36/160 reads (23%) | catalogued as COSV99242117; called by muse, mutect2, varscan2
- RAB17 | c.612G>A p.A204= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs375159510; called by muse, mutect2, varscan2
- RNF123 | c.2595C>T p.F865= | Silent (SNP) | VAF 37/143 reads (26%) | catalogued as COSV100246631; called by muse, mutect2, varscan2
- RNF208 | c.606C>T p.A202= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs540686797, COSV100763093; called by muse, mutect2, varscan2
- RNF213 | c.14872C>A p.R4958= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100300738, COSV60403650; called by muse, mutect2, varscan2
- RTTN | c.21C>T p.I7= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV99732706; called by muse, mutect2, varscan2
- RUNX1T1 | c.12C>G p.V4= | Silent (SNP) | VAF 52/303 reads (17%) | catalogued as COSV56146531, COSV56155055, COSV99752575; called by muse, mutect2, varscan2
- RYR3 | c.13236G>A p.L4412= (on ENST00000389232; = p.L4413= on NM_001036.6) | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1240806955, COSV101212935; called by muse, mutect2, varscan2
- SAMD12 | c.333G>T p.L111= | Silent (SNP) | VAF 59/161 reads (37%) | catalogued as COSV100126179, COSV59053721; called by muse, mutect2, varscan2
- SDF4 | c.567C>A p.V189= | Silent (SNP) | VAF 63/305 reads (21%) | catalogued as COSV99767688; called by muse, mutect2, varscan2
- SEMA3F | c.831C>T p.F277= | Silent (SNP) | VAF 40/153 reads (26%) | catalogued as COSV99137560; called by muse, mutect2, varscan2
- SERPINF2 | c.1380G>A p.L460= | Silent (SNP) | VAF 54/182 reads (30%) | catalogued as COSV60665661; called by muse, mutect2, varscan2
- SIGLEC1 | c.2235C>T p.F745= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as COSV52466462; called by muse, mutect2, varscan2
- SIGLEC8 | c.1320G>C p.G440= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV100367285; called by muse, mutect2, varscan2
- SLC12A5 | c.1629C>A p.P543= (on ENST00000454036 / NM_001134771.2; = p.P520= on NM_020708.5) | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs1346740381, COSV99716204; called by muse, mutect2, varscan2
- SLIT3 | c.1605C>T p.T535= | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as rs1033096222, COSV60631830; called by muse, mutect2, varscan2
- SP140 | c.1869C>T p.F623= | Silent (SNP) | VAF 34/195 reads (17%) | catalogued as COSV100613844; called by muse, mutect2, varscan2
- SPEN | c.8004G>A p.L2668= | Silent (SNP) | VAF 26/230 reads (11%) | catalogued as COSV65364031, COSV65366967; called by muse, mutect2, varscan2
- SPHKAP | c.5070G>A p.L1690= (on ENST00000392056 / NM_001142644.2; = p.L1661= on NM_030623.3) | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as rs769486635, COSV100764169; called by muse, mutect2, varscan2
- SPTBN4 | c.342C>A p.R114= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100151115; called by muse, mutect2, varscan2
- SRGAP3 | c.1845G>A p.Q615= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV100841008; called by muse, mutect2, varscan2
- SRM | c.885C>A p.R295= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as rs750467157, COSV100978955; called by muse, mutect2, varscan2
- SSBP4 | c.1157G>A p.*386= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as COSV99526132; called by muse, mutect2, varscan2
- STK4 | c.628C>T p.L210= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as rs1365765882, COSV100860228; called by muse, mutect2, varscan2
- STX11 | c.684C>T p.F228= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs1206741163, COSV100845497; called by muse, mutect2, varscan2
- STXBP6 | c.462C>T p.I154= | Silent (SNP) | VAF 45/223 reads (20%) | catalogued as COSV100121873, COSV60596633; called by muse, mutect2, varscan2
- TAAR5 | c.15C>T p.F5= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV57799036; called by muse, mutect2, varscan2
- TAS2R40 | c.639C>T p.A213= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as COSV101283006; called by muse, mutect2, varscan2
- TAS2R5 | c.6G>A p.L2= | Silent (SNP) | VAF 45/131 reads (34%) | catalogued as COSV99924807, COSV99924853; called by muse, mutect2, varscan2
- TBCD | c.3264C>T p.L1088= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV100833371; called by muse, mutect2, varscan2
- TC2N | c.390C>T p.F130= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV100562945, COSV61747005; called by muse, mutect2
- THOP1 | c.501C>T p.I167= | Silent (SNP) | VAF 48/145 reads (33%) | catalogued as COSV100310616; called by muse, mutect2, varscan2
- TMC4 | c.1251G>A p.L417= (on ENST00000617472 / NM_001145303.3; = p.L411= on NM_144686.4) | Silent (SNP) | VAF 40/193 reads (21%) | catalogued as COSV99713919; called by muse, mutect2, varscan2
- TRIP10 | c.930C>T p.L310= | Silent (SNP) | VAF 41/110 reads (37%) | catalogued as COSV100505168; called by muse, mutect2, varscan2
- UGGT2 | c.21G>C p.T7= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100942566, COSV65025390; called by muse, mutect2
- USP13 | c.1896C>A p.P632= | Silent (SNP) | VAF 52/231 reads (23%) | catalogued as rs377395498, COSV55863532; called by muse, mutect2, varscan2
- WDR11 | c.3570C>T p.L1190= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as rs745645916, COSV99676632; called by muse, mutect2, varscan2
- WDR90 | c.264C>G p.L88= | Silent (SNP) | VAF 95/784 reads (12%) | catalogued as COSV99553553; called by muse, mutect2, varscan2
- YY1AP1 | c.1011C>T p.I337= (on ENST00000295566 / NM_139118.2; = p.I280= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/203 reads (17%) | catalogued as COSV99804197; called by muse, mutect2, varscan2
- ZBBX | c.739C>T p.L247= | Silent (SNP) | VAF 48/262 reads (18%) | catalogued as rs1220015618, COSV100284205, COSV56792438, COSV56800194; called by muse, mutect2, varscan2
- ZKSCAN2 | c.114G>C p.S38= | Silent (SNP) | VAF 32/150 reads (21%) | catalogued as COSV100048256; called by muse, mutect2, varscan2
- ZNF343 | c.256C>T p.L86= | Silent (SNP) | VAF 41/241 reads (17%) | catalogued as rs1422337145, COSV99601453; called by muse, mutect2, varscan2
- ZNF493 | c.270C>T p.A90= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV100828729; called by muse, mutect2, varscan2
- ZNF574 | c.1512C>T p.F504= | Silent (SNP) | VAF 175/639 reads (27%) | catalogued as COSV99726196; called by muse, mutect2, varscan2
- ANKRD20A5P | n.240G>A | RNA (SNP) | VAF 32/313 reads (10%) | called by muse, mutect2
- DIO3 | chr14:101560306 G>A | 5'Flank (SNP) | VAF 8/27 reads (30%) | catalogued as rs1305123824; called by muse, mutect2, varscan2
- ISCU | c.115-145G>C | Intron (SNP) | VAF 18/180 reads (10%) | catalogued as COSV99934119, COSV99934257; called by muse, mutect2, varscan2
- MIR182 | n.101C>T | RNA (SNP) | VAF 15/46 reads (33%) | catalogued as rs1199450627; called by muse, mutect2, varscan2
- PAQR6 | c.*185G>C | 3'UTR (SNP) | VAF 72/567 reads (13%) | catalogued as COSV99431238; called by muse, mutect2, varscan2
- RUSC1 | c.1358-408C>T | Intron (SNP) | VAF 16/144 reads (11%) | catalogued as COSV99429906; called by muse, mutect2, varscan2
- SUN1 | c.659-287G>T | Intron (SNP) | VAF 65/368 reads (18%) | called by muse, mutect2, varscan2
- ZNF207 | c.551+526C>G | Intron (SNP) | VAF 15/74 reads (20%) | catalogued as rs750085651, COSV100340543; called by muse, mutect2, varscan2
